Somatic mutation profile of tumor specimen TARGET-30-PAIXIF-01A (aliquot TARGET-30-PAIXIF-01A-01W) from TARGET case TARGET-30-PAIXIF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Age at diagnosis: 3.6 years (1,315 days).
Specimen TARGET-30-PAIXIF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72dccc48-a65d-491c-960a-c264974000ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIXIF-10A (Blood Derived Normal), aliquot TARGET-30-PAIXIF-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e29d509-fb6f-4fb3-97c2-ed75d35d3d87

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERD | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs775178619, COSV67533795; called by muse, mutect2, varscan2
- FOSL1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57027434; called by muse, mutect2, varscan2
- KIF20A | c.544C>G p.R182G | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV50145134; called by muse, mutect2, varscan2
- LRP1 | c.8109C>G p.C2703W | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54501857; called by muse, mutect2, varscan2
- MAGEC1 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 227/242 reads (94%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.608); catalogued as COSV53567808, COSV53580633; called by muse, mutect2, varscan2
- OR5H6 | c.175C>T p.L59F (on ENST00000642105; = p.L43F on NM_001005479.2) | Missense Mutation (SNP) | VAF 402/1000 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs867686687, COSV67351013, COSV67352020; called by muse, mutect2
- PRKDC | c.10645C>T p.H3549Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs774139863, COSV58042389; called by muse, mutect2
- SIX2 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV57389883; called by muse, mutect2
- NOC4L | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CSAD | c.213G>T p.L71= (on ENST00000444623 / NM_001244705.2; = p.L98= on NM_015989.5) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57241324; called by muse, mutect2, varscan2
- AC244258.1 | n.828G>T | RNA (SNP) | VAF 64/168 reads (38%) | called by muse, mutect2, varscan2
